Somatic mutation profile of tumor specimen TCGA-2G-AAKH-01A (aliquot TCGA-2G-AAKH-01A-11D-A42Y-10) from TCGA case TCGA-2G-AAKH, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal carcinoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 19.0 years (6,954 days).
Specimen TCGA-2G-AAKH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd137202-9484-4f49-bc8c-25dedfd10422.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2G-AAKH-10A (Blood Derived Normal), aliquot TCGA-2G-AAKH-10A-01D-A433-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a65ef660-3154-4055-bbeb-6b2f8b2be342

The open-access MAF lists 50 somatic variants for this specimen: 36 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 12, Intron 1, RNA 1, Frame Shift Del 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTTNBP2 | c.3895T>C p.S1299P | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV50489590; called by muse, mutect2
- EPS8L3 | c.949C>T p.L317F | Missense Mutation (SNP) | VAF 11/118 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as rs540511118; called by muse, mutect2
- ESF1 | c.1177A>G p.R393G | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as rs1353312131; called by muse, mutect2
- GLI3 | c.2710C>T p.R904C | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67887839; called by muse, mutect2
- GPC6 | c.853G>C p.D285H | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV65507119; called by muse, mutect2, varscan2
- H2BC7 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.028); catalogued as rs1474657409; called by muse, mutect2
- LYST | c.10004G>A p.R3335H | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs528102141; called by muse, mutect2, varscan2
- MCOLN1 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 10/209 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as rs886054695, COSV51176962; ClinVar: uncertain significance; called by muse, mutect2
- NFKB2 | c.1432C>T p.R478C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs1281290020; called by muse, mutect2
- NR0B1 | c.794C>G p.T265R | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM071906, COSV66763604; called by muse, mutect2
- P2RY13 | c.969A>C p.K323N | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV56386161; called by muse, mutect2, varscan2
- PCDHGA4 | c.1162C>G p.Q388E | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.599); catalogued as COSV54015694; called by muse, mutect2, varscan2
- RTL9 | c.1249G>A p.G417R | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV71825451; called by muse, mutect2, varscan2
- SETD3 | c.843del p.N281Kfs*3 | Frame Shift Del (DEL) | VAF 14/151 reads (9%) | catalogued as COSV59283595; called by mutect2, pindel, varscan2
- SMAD6 | c.1405G>T p.A469S | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1416212959; called by muse, mutect2
- ADGRA2 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- CLN3 | c.1166G>A p.C389Y (on ENST00000360019 / NM_001286104.2; = p.C413Y on NM_000086.2) | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2
- DNAJB7 | c.277C>A p.P93T | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.354); called by muse, mutect2
- ETAA1 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FBXW10 | c.2372T>A p.L791* | Nonsense Mutation (SNP) | VAF 28/302 reads (9%) | called by muse, mutect2
- GEMIN5 | c.2918G>A p.C973Y | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HOXA3 | c.72C>A p.F24L | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.012); called by muse, mutect2
- KLRC4 | c.107A>C p.Q36P | Missense Mutation (SNP) | VAF 16/532 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2
- MAPK6 | c.991C>T p.P331S | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- PCLO | c.14357C>T p.T4786I | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PHKA1 | c.2584C>A p.P862T | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SCML2 | c.1070-7_1074del p.X357_splice | Splice Site (DEL) | VAF 22/242 reads (9%) | called by mutect2, pindel
- SETD5 | c.2399C>A p.P800H | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.286); called by muse, mutect2
- SHOC2 | c.58T>C p.S20P | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TACC2 | c.5864C>A p.T1955N (on ENST00000334433; = p.T33N on NM_006997.4) | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAF1B | c.587T>A p.V196D | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.383); called by muse, mutect2
- UBE3D | c.749T>A p.V250D | Missense Mutation (SNP) | VAF 8/220 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2
- USP34 | c.2581A>G p.T861A | Missense Mutation (SNP) | VAF 63/498 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- UTP4 | c.721T>A p.S241T | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- XIAP | c.1358G>T p.C453F | Missense Mutation (SNP) | VAF 34/196 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF506 | c.512A>C p.K171T | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- DENND1C | c.660C>A p.T220= | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as rs771545184, COSV101200160; called by muse, mutect2, varscan2
- GPR45 | c.567C>T p.L189= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as rs1294309045; called by muse, mutect2
- GPR6 | c.996C>T p.R332= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as rs762024685; called by muse, mutect2
- IRX4 | c.621G>A p.T207= | Silent (SNP) | VAF 10/103 reads (10%) | catalogued as rs774523402; called by muse, mutect2, varscan2
- LAMA2 | c.6G>A p.P2= | Silent (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
- LHX8 | c.198C>A p.S66= | Silent (SNP) | VAF 16/248 reads (6%) | catalogued as COSV99633304; called by muse, mutect2
- LTBP3 | c.2538C>T p.G846= | Silent (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- MAGEB4 | c.963T>C p.V321= | Silent (SNP) | VAF 14/106 reads (13%) | called by muse, mutect2, varscan2
- TMEM132D | c.963G>A p.T321= | Silent (SNP) | VAF 18/196 reads (9%) | catalogued as rs777841853; called by muse, mutect2
- TNR | c.2949C>T p.Y983= | Silent (SNP) | VAF 11/113 reads (10%) | catalogued as rs1206369429; called by muse, mutect2
- ZBTB43 | c.1395G>A p.E465= | Silent (SNP) | VAF 55/134 reads (41%) | catalogued as rs765519448; called by muse, mutect2, varscan2
- ZNF614 | c.1428T>C p.C476= | Silent (SNP) | VAF 8/75 reads (11%) | called by muse, mutect2
- GCNT2 | c.926-34828C>G | Intron (SNP) | VAF 9/148 reads (6%) | catalogued as COSV99399122; called by muse, mutect2
- SSPOP | n.3276G>T | RNA (SNP) | VAF 12/92 reads (13%) | called by muse, mutect2, varscan2
